Somatic mutation profile of tumor specimen TCGA-RW-A67X-01A (aliquot TCGA-RW-A67X-01A-11D-A35D-08) from TCGA case TCGA-RW-A67X, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 47.4 years (17,307 days).
Specimen TCGA-RW-A67X-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1c8859c3-8c7d-43ec-82eb-9b0d0f6ad6cc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-RW-A67X-10A (Blood Derived Normal), aliquot TCGA-RW-A67X-10A-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/340ba01e-0096-4bd7-935c-52377f12ceef

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 3, Silent 2, In Frame Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LHX1 | c.520C>A p.Q174K | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.554); catalogued as rs755972632; called by muse, mutect2, varscan2
- SLC9A3 | c.1429G>A p.E477K | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1296904238; called by muse, mutect2
- VHL | c.375_377dup p.D126dup | In Frame Ins (INS) | VAF 37/128 reads (29%) | catalogued as CI071465, COSV56548898; called by mutect2, pindel, varscan2
- ADAMTS3 | c.607A>T p.R203* | Nonsense Mutation (SNP) | VAF 27/199 reads (14%) | called by muse, mutect2, varscan2
- LRP1 | c.2111T>C p.L704P | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- KL | c.2511G>A p.T837= | Silent (SNP) | VAF 22/95 reads (23%) | catalogued as rs36012519; called by muse, mutect2, varscan2
- ZNF70 | c.231A>G p.Q77= | Silent (SNP) | VAF 25/100 reads (25%) | called by muse, mutect2, varscan2
